Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-8468, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-8468-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN SIX (0/6) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN SEVEN (0/7) LYMPH NODES EXAMINED.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, PREDOMINANTLY ACINAR TYPE, WITH ASSOCIATED DUCTAL FEATURES, GLEASON SCORE 4 + 4 = 8.
- B. A TERTIARY PATTERN 3 IS PRESENT IN LESS THAN 5% OF THE TUMOR VOLUME.
- C. THE CARCINOMA INVOLVES LEFT LOBE ONLY AND HAS A GREATEST NODULAR DIAMETER OF 1.8 cm.
- D. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION AT THE POSTERIOR LEFT MID (Slide 3DD).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION IS IDENTIFIED.
- I. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 Mx.
- L. TNM HISTOLOGIC GRADE = G3-4.
- M. BENIGN PROSTATIC NODULAR HYPERPLASIA IS NOTED.

PART 4:

SOFT TISSUE, LEFT APEX PERIRECTAL FAT, RESECTION –

- A. BENIGN FIBROADIPOSE TISSUE.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 25.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	98%
WEIGHT OF PROSTATE:	57.92gm
TUMOR SIZE:	Maximum dimension: 1.8 cm
LOBE LATERALITY:	Left Lobe
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Focal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	13
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 304cb526-a6d7-42a1-95aa-b51c9fd84327 (TCGA-EJ-8468.84D3BC2C-122E-45E7-B9AF-E5F409C95A56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).